MMRF case MMRF_2659 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/151366d7-d4ed-432e-b2b4-ff9d2be6239f

Demographics
Sex at birth: male; Age at index: 62 years; Vital status: Dead; Days to death: 135 days; Cause of death: Not Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 62.8 years (22,941 days); ISS stage: II; Days to last known disease status: 135 days; Days to last follow up: 135 days.
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy.

Follow-up (1 entry)
- Follow-up contacts recording only the day: day -12, day 135.

Molecular and laboratory tests (values rounded to 3 significant figures where GDC's unit conversion carried more)
- Lactate Dehydrogenase 9.22 µkat/L.
- Hemoglobin 6.01 mmol/L.
- Beta 2 Microglobulin 3 µg/mL.
- Albumin 31.8 g/L.
- Serum Free Immunoglobulin Light Chain, Kappa 8.5 mg/dL.
- Serum Free Immunoglobulin Light Chain, Lambda 6161 mg/dL.
- Platelets 245 ×10⁹/L.
- Creatinine 88.4 µmol/L.
- Absolute Neutrophil 3.5 ×10⁹/L.
- M Protein 1.06 g/dL.

Other clinical attributes
- Day -12: Weight: 53 kg; Height: 173 cm.

Biospecimens (2 samples)
- Sample MMRF_2659_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -12 days.
- Sample MMRF_2659_1_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -12 days.
